FM case AD14337 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/1c8efab9-4fd3-4f0d-bc21-239d0d11aa03

Male, 61.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
